Somatic mutation profile of tumor specimen TCGA-38-4632-01A (aliquot TCGA-38-4632-01A-01D-1753-08) from TCGA case TCGA-38-4632, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 42.2 years (15,418 days).
Specimen TCGA-38-4632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8fd0d06-afd3-4149-90f0-ea91710dc914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4632-11A (Solid Tissue Normal), aliquot TCGA-38-4632-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c1ee4b7-387a-4b4a-9e2f-bfe892cf5d70

The open-access MAF lists 548 somatic variants for this specimen: 431 protein-altering or splice-affecting, 101 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 362, Silent 101, Nonsense Mutation 31, Frame Shift Del 17, Splice Site 12, Intron 6, RNA 5, Splice Region 3, Frame Shift Ins 3, In Frame Del 2, 3'Flank 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as CM1313529, CM950459, CX143910, COSV60644274, COSV60648669; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 104/202 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2800A>G p.M934V (on ENST00000303395 / NM_001202435.3; = p.M923V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1559199628, COSV57672149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 29/60 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.1658C>A p.S553Y (on ENST00000404938 / NM_001163941.2; = p.S108Y on NM_178559.6) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51710989, COSV51713608; called by muse, mutect2, varscan2
- AC004593.2 | c.730A>G p.R244G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56093307; called by muse, mutect2, varscan2
- ACAA2 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53271010; called by muse, mutect2, varscan2
- ACSL6 | c.893C>G p.S298* (on ENST00000379240; = p.S323* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV57299277; called by muse, mutect2, varscan2
- ACTR5 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV54760977; called by muse, mutect2, varscan2
- ADAM2 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV55863070; called by muse, mutect2, varscan2
- ADAM33 | c.1389C>G p.C463W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62935027; called by muse, mutect2, varscan2
- ADAMTS18 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV51414758, COSV51419511; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2231G>T p.R744L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV54450705; called by muse, mutect2, varscan2
- ADGRE1 | c.1629G>T p.Q543H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV51676232; called by muse, mutect2, varscan2
- ADGRL3 | c.3516G>A p.M1172I (on ENST00000506720 / NM_001322402.2; = p.M1104I on NM_015236.6) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV72230750; called by muse, mutect2
- ADH4 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55501018; called by muse, mutect2, varscan2
- AEBP2 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56863909; called by muse, mutect2, varscan2
- AFF2 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as COSV60656393, COSV60666708; called by muse, mutect2, varscan2
- AGXT | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56754413; called by muse, mutect2, varscan2
- AK9 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99572396; called by muse, mutect2, varscan2
- ALDH1A2 | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51082792; called by muse, mutect2
- ALLC | c.394T>A p.W132R | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52993005, COSV52995013; called by muse, mutect2
- AMELY | c.377C>A p.P126Q (on ENST00000383036 / NM_001364814.1; = p.P112Q on NM_001143.1) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53095847; called by muse, mutect2, varscan2
- AMOT | c.1492G>T p.E498* (on ENST00000371959 / NM_001113490.1; = p.E89* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 87/189 reads (46%) | catalogued as COSV59064086; called by muse, mutect2, varscan2
- AMOTL1 | c.1327C>A p.Q443K | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs757624588, COSV58567116; called by muse, mutect2, varscan2
- AMPH | c.1253A>T p.Q418L | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV57743665; called by muse, mutect2
- ANAPC4 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs540483057, COSV59544425; called by muse, mutect2, varscan2
- ANK2 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52164120; called by muse, mutect2, varscan2
- ANKRD35 | c.1573C>G p.P525A | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62910521; called by muse, mutect2
- ANKRD44 | c.1996A>T p.K666* | Nonsense Mutation (SNP) | VAF 48/189 reads (25%) | catalogued as COSV56556508; called by muse, mutect2, varscan2
- ANLN | c.2662A>G p.K888E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV56076764; called by muse, mutect2, varscan2
- AP3D1 | c.3122A>T p.H1041L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV61428995; called by muse, mutect2, varscan2
- APOB | c.10807C>A p.H3603N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV51937920; called by muse, mutect2, varscan2
- APTX | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774598658, COSV58928885; called by mutect2, varscan2
- ARHGEF5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs751636255, COSV50211397; called by muse, mutect2
- ARPIN | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773945693, COSV62590144; called by muse, mutect2, varscan2
- ASB5 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs534160855, COSV56671180; called by mutect2, varscan2
- ASTL | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs772118993, COSV60904439; called by muse, mutect2, varscan2
- ATN1 | c.3446A>C p.E1149A | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57546908; called by muse, mutect2, varscan2
- ATP11C | c.2928del p.T977Lfs*10 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV100557489, COSV59564210; called by mutect2, pindel, varscan2
- ATP2B3 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV54849198; called by muse, mutect2, varscan2
- ATP8B3 | c.3393G>T p.E1131D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV59543352; called by muse, mutect2
- ATXN3 | c.419del p.P140Qfs*3 | Frame Shift Del (DEL) | VAF 38/302 reads (13%) | catalogued as COSV61497576; called by mutect2, pindel, varscan2
- B3GNT6 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs558213415, COSV100845763; called by muse, mutect2
- BAAT | c.995A>G p.N332S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); catalogued as rs528729376, COSV52289364; called by muse, mutect2
- BCL11B | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61739185; called by muse, mutect2
- BCR | c.2361G>C p.L787F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV59931957; called by muse, mutect2, varscan2
- BDH2 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56478589; called by muse, mutect2, varscan2
- BIRC6 | c.4982C>T p.A1661V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1262534045, COSV70199949; called by muse, mutect2, varscan2
- BIRC6 | c.9203G>T p.R3068I | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV70199955; called by muse, mutect2, varscan2
- BIRC6 | c.12455C>G p.P4152R | Missense Mutation (SNP) | VAF 36/403 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV70199507, COSV70199960; called by muse, mutect2
- BIRC6 | c.12539A>T p.H4180L | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs1357608002, COSV70199966; called by muse, mutect2, varscan2
- BMS1 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs377531157; called by muse, mutect2, varscan2
- BNC1 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61757719; called by muse, mutect2, varscan2
- BRCC3 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1557292574, COSV57462676; called by muse, varscan2
- BTBD7 | c.2890A>C p.T964P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV58286512; called by muse, mutect2, varscan2
- C1orf141 | c.881A>T p.D294V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV63992759; called by muse, mutect2, varscan2
- C2 | c.987A>G p.K329= | Splice Region (SNP) | VAF 6/37 reads (16%) | catalogued as COSV54960840; called by muse, mutect2, varscan2
- C3orf62 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV57985851; called by muse, mutect2
- C7 | c.1848T>G p.D616E | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV57475210; called by muse, mutect2, varscan2
- CACNG3 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV50069569; called by muse, mutect2, varscan2
- CADM2 | c.364+1G>T p.X122_splice (on ENST00000407528 / NM_001167674.2; = p.X124_splice on NM_153184.4) | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101053378; called by muse, mutect2, varscan2
- CADPS | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV51892970, COSV99336586; called by muse, mutect2, varscan2
- CASP1 | c.1035G>T p.M345I (on ENST00000436863 / NM_033292.4; = p.M324I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV52828320; called by muse, mutect2, varscan2
- CASP9 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601574; called by muse, mutect2, varscan2
- CCDC102B | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60143619; called by muse, mutect2, varscan2
- CD209 | c.947T>C p.M316T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52654493; called by muse, mutect2, varscan2
- CDH13 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51825301; called by muse, mutect2, varscan2
- CDK17 | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV54129633; called by muse, mutect2, varscan2
- CDS1 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55688279; called by muse, mutect2, varscan2
- CENPA | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51982757; called by muse, mutect2, varscan2
- CEP152 | c.3742G>T p.A1248S (on ENST00000380950 / NM_001194998.2; = p.A1192S on NM_014985.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs761611682, COSV57860042; called by muse, mutect2, varscan2
- CEP162 | c.2500G>C p.A834P | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV57620385; called by muse, mutect2, varscan2
- CFC1 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99383451; called by muse, mutect2, varscan2
- CHST2 | c.1407C>A p.F469L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV58885726; called by muse, mutect2, varscan2
- CLSTN2 | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71721196; called by muse, mutect2, varscan2
- CNTN2 | c.2849T>C p.L950P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100084770; called by muse, mutect2
- CNTNAP5 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70482138, COSV70488622; called by muse, mutect2, varscan2
- CNTNAP5 | c.3879G>T p.L1293F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.402); catalogued as COSV70488624; called by muse, mutect2, varscan2
- COL11A1 | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV100616882, COSV62185024; called by muse, mutect2, varscan2
- COL21A1 | c.681T>A p.D227E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV55165103; called by muse, mutect2, varscan2
- COL22A1 | c.3754G>C p.G1252R | Missense Mutation (SNP) | VAF 166/558 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57332308, COSV57339371; called by muse, mutect2, varscan2
- COL6A6 | c.3149C>A p.P1050Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs368734825, COSV100649980; called by muse, mutect2, varscan2
- CORO1A | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1470811661, COSV54631318; called by muse, mutect2
- CORO2B | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418170409, COSV55953578; called by muse, mutect2
- CREB3L3 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV50206263, COSV50256643; called by muse, mutect2, varscan2
- CRISPLD2 | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV52277805, COSV52279894; called by muse, mutect2, varscan2
- CSMD2 | c.8172C>A p.N2724K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53917896; called by muse, mutect2, varscan2
- CSMD3 | c.3556G>T p.G1186C (on ENST00000297405 / NM_001363185.1; = p.G1082C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52196459; called by muse, varscan2
- CSMD3 | c.1918C>A p.H640N (on ENST00000297405 / NM_001363185.1; = p.H536N on NM_052900.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as COSV99828006; called by muse, mutect2, varscan2
- CTIF | c.1739C>G p.P580R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56484849; called by muse, mutect2, varscan2
- CTNNA3 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV57719640; called by muse, mutect2, varscan2
- CXorf21 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100973237; called by muse, mutect2, varscan2
- CYP11B2 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100010781, COSV59997717; called by muse, mutect2, varscan2
- CYP26B1 | c.1162A>G p.K388E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV50012126; called by muse, mutect2, varscan2
- CYP4V2 | c.242C>G p.T81R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as CM150628, COSV66506008; called by muse, mutect2, varscan2
- DAGLA | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV57196589; called by muse, mutect2, varscan2
- DCAF5 | c.2095A>C p.K699Q | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV58460714; called by muse, mutect2
- DCSTAMP | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 35/186 reads (19%) | catalogued as COSV99886219; called by muse, mutect2, varscan2
- DCSTAMP | c.78G>T p.W26C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758551647, COSV52576224, COSV99886221; called by muse, mutect2, varscan2
- DCT | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV65469411; called by mutect2, varscan2
- DDX4 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV61755121; called by muse, mutect2
- DDX43 | c.1496+1G>T p.X499_splice | Splice Site (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100943921; called by muse, mutect2, varscan2
- DMD | c.4081A>T p.R1361W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63759130; called by muse, mutect2, varscan2
- DNAH9 | c.3577-2A>G p.X1193_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52352735; called by muse, mutect2
- DNAJB8 | c.252C>A p.H84Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59878851; called by muse, mutect2, varscan2
- DNAJB9 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV50812209; called by muse, mutect2, varscan2
- DPYD | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV64599279; called by muse, mutect2, varscan2
- DTX4 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57091378; called by muse, mutect2, varscan2
- DUS2 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV62708707; called by muse, mutect2, varscan2
- DUSP22 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753689902, COSV60527518; called by muse, mutect2, varscan2
- DYSF | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV50396971; called by muse, mutect2, varscan2
- ECEL1 | c.2168G>C p.R723P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV58812620; called by muse, mutect2, varscan2
- EHMT1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV58375846; called by muse, mutect2, varscan2
- EPHA3 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100341609, COSV60708592, COSV60729757; called by muse, mutect2, varscan2
- ERICH3 | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58608330; called by muse, mutect2
- ERVW-1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as COSV101423814; called by muse, mutect2, varscan2
- EYA4 | c.1070C>A p.S357Y (on ENST00000531901 / NM_001301013.1; = p.S351Y on NM_004100.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV100765388; called by muse, mutect2
- FAM131B | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV68125522, COSV68126213; called by muse, mutect2, varscan2
- FAM135B | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52728873; called by muse, mutect2, varscan2
- FAM47B | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61454297; called by muse, mutect2, varscan2
- FARP2 | c.2490C>G p.I830M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV50872013; called by muse, mutect2, varscan2
- FAT1 | c.3869G>T p.S1290I | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71674426; called by muse, mutect2, varscan2
- FAT3 | c.3886G>T p.V1296L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.447); catalogued as COSV53119124; called by muse, mutect2, varscan2
- FCGR3A | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780437274, COSV63459729; called by muse, mutect2, varscan2
- FER1L6 | c.3094C>T p.Q1032* | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | catalogued as rs779072312, COSV67550361; called by muse, mutect2
- FGD5 | c.1565C>A p.T522K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV53244271; called by muse, mutect2, varscan2
- FGFBP2 | c.275G>A p.W92* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as rs1369804668, COSV99469350; called by muse, mutect2, varscan2
- FHOD3 | c.2694G>A p.W898* (on ENST00000359247 / NM_001281739.3; = p.W915* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV57174813; called by muse, mutect2, varscan2
- FLG2 | c.3655G>T p.G1219C | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV101165671; called by muse, mutect2, varscan2
- FLG2 | c.3654G>T p.L1218F | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101165674; called by muse, mutect2, varscan2
- FLT4 | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761339590, COSV56110348, COSV56118593; called by muse, mutect2, varscan2
- FMNL1 | c.3229T>G p.F1077V | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV58957272; called by muse, mutect2
- FOXC2 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs764129123, COSV100234149; called by muse, mutect2, varscan2
- FOXN3 | c.859C>G p.L287V (on ENST00000261302; = p.L265V on NM_005197.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV54310055; called by muse, mutect2, varscan2
- FRMPD4 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV66215896; called by muse, mutect2, varscan2
- GABRB1 | c.173-1G>T p.X58_splice | Splice Site (SNP) | VAF 39/225 reads (17%) | catalogued as COSV54983960; called by muse, mutect2, varscan2
- GABRB1 | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.812); catalogued as COSV54983973, COSV55004304; called by muse, mutect2
- GABRB3 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV54663541; called by muse, mutect2, varscan2
- GABRG2 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62715564; called by muse, mutect2, varscan2
- GABRP | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs868219208, COSV54663163; called by muse, mutect2, varscan2
- GALNTL6 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 23/117 reads (20%) | catalogued as COSV72491251; called by muse, mutect2, varscan2
- GCKR | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53108340; called by muse, mutect2
- GGPS1 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99270366; called by muse, mutect2, varscan2
- GINS3 | c.407A>T p.Q136L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100139229; called by muse, mutect2, varscan2
- GMDS | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV66435108; called by muse, mutect2, varscan2
- GML | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375056481; called by muse, mutect2
- GPA33 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.567); catalogued as rs1469329036, COSV63301220; called by muse, mutect2
- GPD1L | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56990299; called by muse, mutect2
- GPR158 | c.2284C>A p.P762T | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542611999, COSV66265358; called by muse, mutect2, varscan2
- GRHL2 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV52549131; called by muse, mutect2, varscan2
- GSG1L | c.912C>A p.H304Q (on ENST00000447459 / NM_001109763.2; = p.H149Q on NM_144675.2) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.88); catalogued as COSV66579087; called by muse, mutect2, varscan2
- HBG2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57962846, COSV57963763; called by muse, mutect2, varscan2
- HEATR5A | c.5003A>T p.E1668V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs754663399, COSV66341545; called by muse, mutect2, varscan2
- HECTD4 | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as rs762098805, COSV61179596; called by muse, mutect2
- HEPH | c.1285T>A p.W429R (on ENST00000343002; = p.W162R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.943); catalogued as COSV57964961; called by muse, mutect2, varscan2
- HERC2 | c.5087G>T p.W1696L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55326822; called by muse, mutect2, varscan2
- HGF | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55950541, COSV99738608; called by muse, mutect2, varscan2
- HMMR | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.059); catalogued as COSV62374606; called by muse, mutect2, varscan2
- HNRNPM | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57692881; called by muse, mutect2, varscan2
- HOXC10 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV100329035, COSV57726981; called by muse, mutect2, varscan2
- HOXD3 | c.100T>G p.Y34D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV50881040; called by muse, mutect2
- HSPA2 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99904753; called by muse, mutect2, varscan2
- HTR2A | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101096609; called by muse, mutect2, varscan2
- HYDIN | c.6822G>T p.K2274N | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59258687; called by muse, mutect2, varscan2
- ICE1 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.273); catalogued as COSV56826447; called by muse, mutect2, varscan2
- IFNA17 | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV101303441; called by muse, mutect2, varscan2
- IGHM | c.482C>A p.T161K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs782737651; called by muse, mutect2
- IL18RAP | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as COSV51826411; called by muse, mutect2, varscan2
- IL1RAPL1 | c.950T>A p.I317N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV56266125; called by muse, mutect2, varscan2
- IL23R | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.061); catalogued as rs749335735, COSV61372480; called by muse, mutect2, varscan2
- IPO8 | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.272); catalogued as rs1263217731, COSV56242142; called by muse, mutect2, varscan2
- ITPRID1 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60075668; called by muse, mutect2, varscan2
- IZUMO2 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53230244, COSV53231213; called by muse, mutect2, varscan2
- KCNH3 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1025805929, COSV57791088; called by muse, mutect2, varscan2
- KCNT2 | c.2974C>G p.H992D | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54082933; called by muse, mutect2, varscan2
- KCNT2 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV54074234; called by muse, mutect2, varscan2
- KIAA0895 | c.729A>T p.K243N (on ENST00000297063 / NM_001100425.2; = p.K192N on NM_015314.3) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51711133; called by muse, mutect2, varscan2
- KIF1B | c.1717G>T p.G573W (on ENST00000377086 / NM_001365952.1; = p.G527W on NM_015074.3) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55809597, COSV55809675; called by muse, mutect2, varscan2
- KL | c.1185G>C p.R395S | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66308929; called by muse, mutect2, varscan2
- KLHL40 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs746097011, COSV55134824; called by muse, mutect2, varscan2
- KMT2C | c.8300G>T p.G2767V | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV51446290; called by muse, mutect2, varscan2
- KRT31 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs773850073, COSV99289481; called by muse, mutect2, varscan2
- KRTAP10-2 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59964769; called by muse, mutect2
- KYNU | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51584504; called by muse, mutect2, varscan2
- LAMB2 | c.798C>G p.I266M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100565201, COSV59734111; called by muse, mutect2
- LCP2 | c.186G>C p.V62= | Splice Region (SNP) | VAF 5/70 reads (7%) | catalogued as COSV50448718, COSV50451838; called by muse, mutect2
- LCT | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51550683; called by muse, mutect2, varscan2
- LGALS9B | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100162897; called by mutect2, varscan2
- LLCFC1 | c.319C>A p.Q107K (on ENST00000458732; = p.Q76K on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV100786923; called by muse, varscan2
- LRP1B | c.3997G>A p.G1333S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754823493, COSV67227646; called by muse, mutect2, varscan2
- LRP2 | c.13840C>T p.P4614S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1222400860, COSV99787037; called by muse, mutect2, varscan2
- LRRC8C | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV64998449; called by muse, mutect2, varscan2
- LRRC8D | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as COSV61579570; called by muse, mutect2, varscan2
- LRRTM4 | c.924del p.L308Ffs*30 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV101297756; called by mutect2, pindel*, varscan2
- LTBP1 | c.3061C>T p.Q1021* (on ENST00000404816 / NM_206943.4; = p.Q695* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV63188581; called by muse, mutect2, varscan2
- LTBP4 | c.1293C>G p.C431W (on ENST00000308370 / NM_001042544.1; = p.C394W on NM_003573.2) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52582517; called by muse, mutect2, varscan2
- LVRN | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1241412353, COSV63497401; called by muse, mutect2, varscan2
- MAGEA10 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | catalogued as COSV54884189, COSV99726826; called by muse, mutect2, varscan2
- MAGEB6B | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV69689632; called by muse, mutect2, varscan2
- MAGEC1 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV53573823; called by muse, mutect2, varscan2
- MAGI2 | c.539-1G>T p.X180_splice | Splice Site (SNP) | VAF 26/166 reads (16%) | catalogued as COSV62664882; called by muse, mutect2
- MAP7D3 | c.2314A>T p.T772S | Missense Mutation (SNP) | VAF 135/259 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60171130; called by muse, mutect2, varscan2
- MARCO | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59052652, COSV59055135; called by muse, mutect2, varscan2
- MC5R | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV61254822; called by muse, mutect2, varscan2
- MCM10 | c.2021C>A p.T674K (on ENST00000484800 / NM_182751.3; = p.T673K on NM_018518.5) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV66334698; called by muse, mutect2, varscan2
- MDGA1 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51796520; called by muse, mutect2, varscan2
- MED1 | c.2429C>A p.S810Y | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56125340, COSV56125385; called by muse, mutect2, varscan2
- MED30 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV52067395; called by muse, mutect2, varscan2
- METTL23 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 55/238 reads (23%) | catalogued as COSV100333581; called by muse, mutect2, varscan2
- MICU3 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV58846420; called by muse, mutect2, varscan2
- MPEG1 | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57091384; called by muse, mutect2, varscan2
- MPEG1 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV57091390; called by muse, mutect2, varscan2
- MRPL14 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.081); catalogued as rs1440877733, COSV64394571; called by muse, mutect2, varscan2
- MSANTD4 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs773317277, COSV100108540; called by muse, mutect2, varscan2
- MUC21 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100888841, COSV66222102; called by muse, mutect2, varscan2
- MYOCD | c.1996G>T p.G666W | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58502595, COSV58504710, COSV58505237; called by muse, mutect2, varscan2
- NAT8 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99721937; called by muse, mutect2
- NAV3 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57083635; called by muse, mutect2, varscan2
- NDUFB4 | c.327+1G>A p.X109_splice | Splice Site (SNP) | VAF 13/177 reads (7%) | catalogued as COSV51742333; called by muse, mutect2
- NELL1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54271098, COSV54295994; called by muse, mutect2, varscan2
- NELL2 | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV61576208; called by muse, mutect2, varscan2
- NEO1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.391); catalogued as COSV99981429; called by muse, mutect2, varscan2
- NEURL1 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100872689; called by muse, mutect2
- NEUROD6 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV51771629, COSV51771658; called by muse, mutect2
- NLGN4X | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV52020736; called by muse, mutect2, varscan2
- NLRP7 | c.2130-2A>G p.X710_splice (on ENST00000340844 / NM_206828.3; = p.X682_splice on NM_139176.3) | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs764734665, CS148056, COSV60175582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS2 | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201569440, COSV58224292; called by muse, mutect2, varscan2
- NRXN1 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV58457619, COSV58487084; called by muse, mutect2, varscan2
- NUP210 | c.5223G>T p.W1741C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV99595766; called by muse, mutect2
- NXPE4 | c.1484A>T p.Q495L (on ENST00000375478 / NM_001077639.2; = p.Q211L on NM_017678.3) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs766558030, COSV64943825; called by muse, mutect2, varscan2
- OR10C1 | c.628T>C p.C210R (on ENST00000622521; = p.C208R on NM_013941.3) | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV65823044; called by muse, mutect2, varscan2
- OR10G9 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | catalogued as COSV66686354; called by muse, varscan2
- OR14A16 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV62926735, COSV62926970; called by muse, mutect2, varscan2
- OR1S2 | c.977G>C p.*326Sext*? | Nonstop Mutation (SNP) | VAF 28/151 reads (19%) | catalogued as COSV100224049; called by muse, mutect2, varscan2
- OR2B11 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV59510401; called by muse, varscan2
- OR2F1 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as COSV67331493; called by muse, mutect2
- OR2W3 | c.105C>A p.Y35* | Nonsense Mutation (SNP) | VAF 40/117 reads (34%) | catalogued as rs1311925561, COSV64457053; called by muse, mutect2, varscan2
- OR4A15 | c.563C>A p.T188N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs776246350, COSV59035563; called by muse, mutect2, varscan2
- OR4Q3 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59178840; called by muse, mutect2, varscan2
- OR5J2 | c.290del p.C97Sfs*21 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as COSV56623172; called by mutect2, pindel, varscan2
- OR6F1 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV57468056; called by muse, mutect2, varscan2
- OR6K6 | c.334T>A p.C112S (on ENST00000368144; = p.C88S on NM_001005184.1) | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV63744268; called by muse, mutect2
- OR6N1 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763628231, COSV58648800; called by muse, mutect2, varscan2
- OR7C2 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); catalogued as rs537843072, COSV50180826; called by muse, mutect2, varscan2
- OR8B8 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV60144755; called by muse, mutect2, varscan2
- OR8K1 | c.618G>T p.L206F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); catalogued as COSV99687168; called by muse, mutect2, varscan2
- OR8K5 | c.264T>A p.D88E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV57889296; called by muse, mutect2, varscan2
- OTOA | c.1964C>A p.P655H (on ENST00000286149; = p.P641H on NM_144672.4) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV53755661; called by muse, mutect2, varscan2
- OTOL1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100019806, COSV60006681; called by muse, mutect2, varscan2
- P3H3 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99300967; called by muse, mutect2, varscan2
- PAGE2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | catalogued as COSV100892292; called by muse, mutect2, varscan2
- PAPPA2 | c.1706T>A p.V569D | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV62779295; called by muse, mutect2, varscan2
- PBX3 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60732322, COSV60732584; called by muse, mutect2, varscan2
- PCDH10 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52095609, COSV52099314; called by muse, mutect2, varscan2
- PCDHA6 | c.552A>G p.I184M | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV65352042, COSV65352896; called by muse, mutect2, varscan2
- PCDHGA12 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52754055; called by muse, mutect2
- PCDHGA5 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV53960433; called by muse, mutect2, varscan2
- PCDHGA6 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV53960452; called by muse, mutect2, varscan2
- PCK1 | c.1299T>A p.F433L | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV60128568; called by muse, mutect2, varscan2
- PDGFRA | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV57268894; called by muse, mutect2, varscan2
- PDHA2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54779080, COSV54779524; called by muse, mutect2, varscan2
- PDSS2 | c.815A>C p.H272P | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64655205; called by muse, mutect2, varscan2
- PEG3 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.628); catalogued as rs867906698, COSV55635634; called by muse, mutect2, varscan2
- PFKP | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV66898389; called by muse, mutect2, varscan2
- PHACTR3 | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV63028743; called by muse, mutect2, varscan2
- PI4KA | c.1420G>C p.V474L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55412505; called by muse, mutect2, varscan2
- PKD1L1 | c.2209A>T p.R737* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV56966825; called by muse, mutect2
- PLOD3 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.753); catalogued as COSV56183253; called by muse, mutect2, varscan2
- PLXNB2 | c.4970T>A p.F1657Y | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63782127; called by muse, mutect2, varscan2
- POU2F3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1465658817, COSV52794357; called by muse, mutect2, varscan2
- PPP2R2B | c.335-2A>T p.X112_splice (on ENST00000394409; = p.X178_splice on NM_181674.2) | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV60766071; called by muse, mutect2
- PRDM14 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52572782; called by muse, mutect2
- PRKD1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59571132; called by muse, mutect2, varscan2
- PSG7 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV68445305; called by muse, mutect2, varscan2
- PTPRC | c.3874C>A p.H1292N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV61412895; called by muse, mutect2, varscan2
- PTPRD | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100643859, COSV61981700; called by muse, varscan2
- PTPRD | c.538T>A p.S180T | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.847); catalogued as COSV100643862; called by muse, mutect2, varscan2
- PTPRT | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV61985490; called by muse, mutect2, varscan2
- RAB42 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765050696, COSV100866068; called by muse, mutect2, varscan2
- RALYL | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV101569075; called by muse, mutect2, varscan2
- RALYL | c.773C>G p.P258R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV101569076, COSV72825778; called by muse, mutect2, varscan2
- RASGRP3 | c.1525G>T p.E509* (on ENST00000402538 / NM_001349975.2; = p.E508* on NM_015376.2 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV67821186, COSV67822337; called by muse, mutect2, varscan2
- REG3G | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751348515, COSV55449888; called by muse, mutect2
- RIF1 | c.3257T>G p.L1086R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54617999; called by muse, mutect2, varscan2
- RIMS2 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68113151; called by muse, mutect2, varscan2
- RIMS2 | c.995G>T p.R332L (on ENST00000666250 / NM_001348490.2; = p.R140L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51686773; called by muse, mutect2
- RIMS2 | c.1273G>A p.A425T (on ENST00000666250 / NM_001348490.2; = p.A233T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.024); catalogued as rs1326673520, COSV51686803; called by muse, mutect2, varscan2
- RIN1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748150722, COSV60926912; called by muse, mutect2, varscan2
- RLF | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.535); catalogued as COSV65652061; called by muse, mutect2, varscan2
- RNF103 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs1405953257, COSV52895115; called by muse, mutect2, varscan2
- RNF144A | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57982833; called by muse, mutect2
- RP1L1 | c.5230G>T p.E1744* | Nonsense Mutation (SNP) | VAF 36/149 reads (24%) | catalogued as rs1257867093, COSV66755897; called by muse, mutect2, varscan2
- RP1L1 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV66755902; called by muse, mutect2, varscan2
- RPGRIP1L | c.1714A>C p.I572L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV50907834; called by muse, mutect2
- RUNDC3B | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as rs773011983, COSV56693716; called by muse, mutect2, varscan2
- RYR1 | c.3652C>A p.L1218I | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62099135; called by muse, mutect2, varscan2
- RYR2 | c.10307A>T p.K3436M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV63688673; called by muse, mutect2, varscan2
- S1PR3 | c.250T>C p.C84R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV63980712; called by muse, varscan2
- SAAL1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55515919; called by muse, mutect2, varscan2
- SAXO1 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs149549686; called by muse, mutect2, varscan2
- SCN1A | c.5839A>G p.I1947V (on ENST00000303395 / NM_001202435.3; = p.I1936V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57672099; called by muse, mutect2, varscan2
- SCN1A | c.5624T>C p.V1875A (on ENST00000303395 / NM_001202435.3; = p.V1864A on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57672129; called by muse, mutect2
- SCN2A | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51843260; called by muse, mutect2, varscan2
- SCN4A | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV71127154; called by muse, mutect2, varscan2
- SEC23A | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV56974624; called by muse, mutect2, varscan2
- SELP | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55252843; called by muse, mutect2, varscan2
- SF1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57114322, COSV99918405; called by muse, mutect2, varscan2
- SFPQ | c.1861G>T p.G621* | Nonsense Mutation (SNP) | VAF 11/190 reads (6%) | catalogued as COSV61758236, COSV61758734; called by muse, mutect2
- SH2D7 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100174603; called by muse, mutect2
- SHISA4 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV62884598; called by muse, mutect2, varscan2
- SHQ1 | c.1422T>A p.D474E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV57765901; called by muse, mutect2, varscan2
- SLAMF8 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV56988017, COSV56988730; called by muse, mutect2, varscan2
- SLC12A1 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101118379; called by muse, mutect2
- SLC12A1 | c.2045C>A p.P682H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101118382; called by muse, mutect2
- SLC1A3 | c.1337C>A p.A446E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1038146073, COSV54317019, COSV54320645; called by muse, mutect2, varscan2
- SLC1A6 | c.203T>A p.I68N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99693505; called by mutect2, varscan2
- SLC30A8 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69971150; called by muse, mutect2, varscan2
- SLC32A1 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54146924; called by muse, mutect2, varscan2
- SLC4A11 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.951); catalogued as COSV66262173; called by muse, mutect2
- SLC4A4 | c.1500C>A p.G500= (on ENST00000264485 / NM_001098484.3; = p.G456= on NM_003759.4) | Splice Region (SNP) | VAF 17/145 reads (12%) | catalogued as rs373128647, COSV52625740; called by muse, mutect2, varscan2
- SLC5A8 | c.967A>T p.M323L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV73310719; called by muse, mutect2, varscan2
- SLC8A1 | c.2639T>A p.L880Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60482366; called by muse, mutect2, varscan2
- SLC9A2 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52132129, COSV52132722; called by muse, mutect2, varscan2
- SLC9A9 | c.1879G>T p.G627C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57227759; called by muse, mutect2, varscan2
- SLCO5A1 | c.2153A>T p.Q718L | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV52660514; called by muse, mutect2, varscan2
- SMG8 | c.1807A>C p.S603R | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56285606; called by muse, mutect2, varscan2
- SNTG1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV52447453; called by muse, mutect2, varscan2
- SORCS1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV53870797; called by muse, mutect2, varscan2
- SORCS1 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as rs773703545, COSV53870813; called by muse, mutect2, varscan2
- SPANXN4 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100980944; called by muse, mutect2, varscan2
- SPATA31D1 | c.1685C>G p.P562R | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61196536; called by muse, mutect2
- SPTA1 | c.5875G>C p.D1959H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1365504739, COSV100935526, COSV63754222; called by muse, mutect2, varscan2
- SPTBN2 | c.4455G>T p.Q1485H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.612); catalogued as COSV59453229; called by muse, mutect2, varscan2
- SRRT | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV52341905; called by muse, mutect2, varscan2
- STAP2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55696396; called by muse, mutect2, varscan2
- STARD4 | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56968128; called by muse, mutect2
- STT3B | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55503038; called by muse, varscan2
- SUN5 | c.572del p.G191Efs*11 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | catalogued as COSV62180086; called by mutect2, pindel, varscan2
- SV2C | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59221086; called by muse, mutect2, varscan2
- SVEP1 | c.9355C>T p.P3119S | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as COSV52839893; called by muse, mutect2, varscan2
- SVEP1 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV57037658; called by muse, mutect2
- SYT10 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57341102; called by muse, mutect2, varscan2
- TAF1C | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs138550395; called by muse, mutect2, varscan2
- TAS2R40 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101282982; called by muse, mutect2
- TBX15 | c.620A>T p.D207V (on ENST00000369429 / NM_001330677.2; = p.D101V on NM_152380.3) | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52871775; called by muse, mutect2, varscan2
- TCF23 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); catalogued as COSV56079022, COSV99940296; called by muse, mutect2, varscan2
- TGM1 | c.1399A>T p.S467C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV52863404; called by muse, mutect2
- THUMPD2 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53187810; called by muse, mutect2, varscan2
- TLR4 | c.1559C>A p.S520Y (on ENST00000355622 / NM_138554.5; = p.S480Y on NM_003266.4) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62923426; called by muse, mutect2, varscan2
- TM2D1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs369821446, COSV53906711; called by mutect2, varscan2
- TMEM266 | c.1517C>A p.P506H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV66379681; called by muse, mutect2, varscan2
- TMPRSS15 | c.33T>A p.H11Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV53040882; called by muse, mutect2, varscan2
- TMPRSS4 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV71109357; called by muse, mutect2
- TNFRSF13B | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as rs764951604, COSV55428124; called by muse, mutect2, varscan2
- TNR | c.246del p.L83* | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | catalogued as COSV54911778; called by mutect2, varscan2
- TOR1AIP2 | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV62626223; called by muse, mutect2, varscan2
- TRIB2 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767148205, COSV50226106; called by muse, mutect2, varscan2
- TRIM28 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs758388758, COSV53400486; called by muse, mutect2, varscan2
- TRIO | c.5551G>T p.G1851W | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60084957; called by muse, mutect2, varscan2
- TRPC7 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61458489; called by muse, mutect2, varscan2
- TRPS1 | c.3359C>G p.S1120C (on ENST00000220888 / NM_001330599.2; = p.S1133C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55242987; called by muse, mutect2
- TTN | c.71636T>A p.I23879K (on ENST00000591111; = p.I16455K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | PolyPhen benign (0.421); catalogued as COSV100600111; called by muse, mutect2, varscan2
- TTN | c.18013T>C p.S6005P (on ENST00000591111; = p.S5078P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | PolyPhen benign (0.326); catalogued as COSV60104049; called by muse, mutect2, varscan2
- UBE2M | c.549A>T p.K183N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV53397039; called by muse, mutect2
- UBE4B | c.2555A>T p.Q852L (on ENST00000343090 / NM_001105562.3; = p.Q723L on NM_006048.5) | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV53533590; called by muse, mutect2, varscan2
- UBXN2B | c.471T>A p.D157E | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as COSV68309118; called by muse, mutect2
- UGDH | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57098013; called by muse, mutect2, varscan2
- UGT2B4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs767979359, COSV59316327; called by muse, mutect2, varscan2
- UGT2B4 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59317689, COSV59319705; called by muse, varscan2
- UGT3A1 | c.360A>T p.Q120H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV57098617; called by muse, mutect2, varscan2
- UGT8 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs371402834; called by muse, mutect2, varscan2
- USP33 | c.1370-1G>T p.X457_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62469731; called by muse, mutect2
- USP36 | c.3334C>G p.H1112D | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61751940, COSV61753260; called by muse, mutect2, varscan2
- VPS16 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV66795557; called by muse, mutect2, varscan2
- VWA3B | c.2106G>T p.L702F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV101345966; called by muse, mutect2
- XIRP2 | c.5935A>G p.T1979A (on ENST00000628543; = p.T2154A on NM_152381.6) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54704338; called by muse, mutect2
- XKR6 | c.1191G>T p.M397I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58656333, COSV58656560; called by muse, mutect2, varscan2
- XPNPEP1 | c.1452+1G>A p.X484_splice | Splice Site (SNP) | VAF 14/184 reads (8%) | catalogued as COSV59168443; called by muse, mutect2
- YIPF7 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60656958; called by muse, mutect2, varscan2
- ZAP70 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53854632; called by muse, mutect2
- ZBBX | c.849T>A p.H283Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100284372, COSV56790973; called by muse, mutect2
- ZBTB14 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.539); catalogued as COSV63696818; called by muse, mutect2, varscan2
- ZBTB45 | c.1263C>A p.H421Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99564229; called by muse, mutect2, varscan2
- ZC3H12B | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350523612, COSV59048525, COSV59049733; called by muse, mutect2, varscan2
- ZC3H3 | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as rs1015162889, COSV52790471; called by muse, mutect2
- ZFHX4 | c.9216C>A p.D3072E | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.447); catalogued as COSV50891760, COSV99262277; called by muse, mutect2, varscan2
- ZFHX4 | c.10780G>T p.V3594L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.725); catalogued as COSV50892461; called by muse, varscan2
- ZFP64 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53798925, COSV53803475, COSV99402108; called by muse, varscan2
- ZFPM2 | c.1598G>C p.S533T | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV101023288, COSV65873983; called by muse, mutect2, varscan2
- ZIC4 | c.48C>A p.Y16* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV67172101; called by muse, mutect2, varscan2
- ZMAT4 | c.574A>T p.R192* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV52701000; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766674328, COSV101031875, COSV65639933; called by muse, mutect2
- ZNF121 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV57551727, COSV57552707; called by muse, mutect2, varscan2
- ZNF229 | c.1621G>T p.G541* | Nonsense Mutation (SNP) | VAF 16/296 reads (5%) | catalogued as COSV52162318, COSV52164846; called by muse, mutect2
- ZNF300 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as COSV51036194; called by muse, mutect2, varscan2
- ZNF304 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV56584544; called by muse, mutect2, varscan2
- ZNF318 | c.4745A>T p.E1582V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV58933093; called by muse, mutect2, varscan2
- ZNF366 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.026); catalogued as rs765523103, COSV100574137; called by muse, mutect2, varscan2
- ZNF385D | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55758150; called by muse, mutect2, varscan2
- ZNF416 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52184722; called by muse, mutect2, varscan2
- ZNF423 | c.3024G>T p.E1008D (on ENST00000563137 / NM_001379286.1; = p.E1000D on NM_015069.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52190791; called by muse, mutect2
- ZNF514 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1345668258, COSV54634170; called by muse, mutect2, varscan2
- ZNF547 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.601); catalogued as COSV56580669, COSV56582602; called by muse, mutect2, varscan2
- ZNF829 | c.697A>T p.I233F | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV66986476; called by muse, mutect2
- ABCB1 | c.1646C>A p.P549H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGAP3 | c.2073_2074del p.A692Cfs*27 (on ENST00000622464; = p.A728Cfs*27 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/141 reads (14%) | called by mutect2, pindel*, varscan2*
- ALOX5AP | c.28del p.V10Sfs*52 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- BLMH | c.1022_1023del p.M341Kfs*4 | Frame Shift Del (DEL) | VAF 84/334 reads (25%) | called by mutect2, pindel*, varscan2*
- C10orf71 | c.269del p.T90Rfs*44 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- CACNB2 | c.543_567del p.N181Kfs*23 (on ENST00000324631 / NM_201596.3; = p.N126Kfs*23 on NM_000724.4) | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- EPHA8 | c.313_321del p.L105_D107del | In Frame Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- GDF10 | c.712A>T p.S238C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HPSE2 | c.611-1G>T p.X204_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2
- IGHA1 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2
- IGKV1-17 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV2-30 | c.345A>C p.Q115H | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2
- JADE2 | c.1988del p.D663Afs*5 | Frame Shift Del (DEL) | VAF 20/141 reads (14%) | called by mutect2, pindel, varscan2
- JHY | c.788dup p.L263Ffs*17 | Frame Shift Ins (INS) | VAF 51/345 reads (15%) | called by mutect2, pindel, varscan2
- KCNT2 | c.1887del p.I629Mfs*5 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- MYH9 | c.443dup p.H149Sfs*27 | Frame Shift Ins (INS) | VAF 12/116 reads (10%) | called by mutect2, pindel
- NBPF26 | c.1913A>G p.E638G (on ENST00000620612; = p.E376G on NM_001351372.1) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by mutect2, varscan2
- PRAMEF5 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PTCD1 | c.477dup p.E160* | Frame Shift Ins (INS) | VAF 54/158 reads (34%) | called by pindel, varscan2*
- ROCK1 | c.796del p.V266Yfs*8 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- SPIRE2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- SRRM2 | c.2934_2935delinsT p.K978Nfs*2 | Frame Shift Del (DEL) | VAF 26/215 reads (12%) | called by muse*, pindel
- TEX15 | c.4559del p.N1520Ifs*9 (on ENST00000256246; = p.N1903Ifs*9 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- TRERF1 | c.1445_1468del p.L482_G490delinsR | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- TTN | c.15730del p.T5244Pfs*3 (on ENST00000591111; = p.T4317Pfs*3 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/141 reads (11%) | called by mutect2, pindel*, varscan2
- VCX | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCG4 | c.1314C>A p.A438= | Silent (SNP) | VAF 124/191 reads (65%) | catalogued as COSV56643810; called by muse, mutect2, varscan2
- ACP7 | c.832C>A p.R278= | Silent (SNP) | VAF 58/172 reads (34%) | catalogued as COSV58699513; called by muse, mutect2, varscan2
- ADAMTS13 | c.3687C>T p.V1229= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV52468845; called by muse, mutect2, varscan2
- ADGRB3 | c.2950T>C p.L984= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53246848; called by muse, mutect2, varscan2
- ADGRG4 | c.3984G>A p.L1328= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as rs1275749556, COSV54957545; called by muse, mutect2, varscan2
- ADRA2B | c.432G>T p.S144= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV69787632, COSV69788442; called by muse, mutect2, varscan2
- ALDH1L1 | c.399C>A p.S133= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56411708, COSV56414727; called by muse, mutect2, varscan2
- ANP32E | c.543G>C p.P181= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV58482397; called by muse, mutect2, varscan2
- ARCN1 | c.1083G>T p.V361= | Silent (SNP) | VAF 338/532 reads (64%) | catalogued as COSV50615321; called by muse, mutect2, varscan2
- ARSF | c.312C>A p.V104= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV63839787; called by muse, mutect2, varscan2
- ASCC3 | c.2724T>C p.T908= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV61228903; called by muse, mutect2, varscan2
- ASTN1 | c.2178G>T p.G726= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV56070884, COSV99922716; called by muse, mutect2, varscan2
- BMPER | c.1170G>A p.L390= | Silent (SNP) | VAF 10/185 reads (5%) | catalogued as COSV51820093, COSV51826567; called by muse, mutect2
- CD6 | c.1821C>A p.T607= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV57839183; called by muse, mutect2, varscan2
- CDC23 | c.270C>T p.A90= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV67508462; called by muse, mutect2
- CLN5 | c.204T>G p.P68= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV66284237; called by muse, mutect2
- CLN5 | c.309A>G p.E103= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV66284246; called by muse, mutect2
- CNBD1 | c.735A>G p.T245= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV72976198; called by muse, mutect2, varscan2
- CNTNAP2 | c.738C>A p.V246= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV62189140, COSV62231177; called by muse, mutect2, varscan2
- COL4A5 | c.4359T>A p.P1453= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV60362894; called by muse, mutect2, varscan2
- COL6A3 | c.5532T>C p.D1844= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99796632; called by muse, mutect2, varscan2
- CR1L | c.711T>C p.N237= | Silent (SNP) | VAF 95/454 reads (21%) | catalogued as COSV54326862; called by muse, mutect2, varscan2
- CSMD1 | c.7245T>A p.T2415= (on ENST00000520002; = p.T2414= on NM_033225.6) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs539478192, COSV59331791; called by muse, mutect2, varscan2
- CSTL1 | c.387C>A p.L129= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV55677703, COSV99851093; called by muse, mutect2, varscan2
- CYP7A1 | c.228C>T p.V76= | Silent (SNP) | VAF 7/163 reads (4%) | catalogued as COSV56963934; called by muse, mutect2
- DDX42 | c.1791G>T p.V597= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV63790290; called by muse, mutect2
- DLD | c.1086G>A p.L362= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV52738250; called by muse, mutect2, varscan2
- DOCK1 | c.3525G>A p.V1175= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54742137; called by muse, mutect2, varscan2
- DPPA5 | c.91C>A p.R31= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1252349128, COSV64875634, COSV64875772; called by muse, mutect2, varscan2
- EFCC1 | c.1796G>A p.*599= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV71401877; called by muse, mutect2, varscan2
- ELFN2 | c.201C>G p.L67= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV68744773; called by muse, mutect2, varscan2
- ENGASE | c.1203C>T p.V401= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV56135900; called by muse, mutect2, varscan2
- ERCC4 | c.1179A>T p.A393= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as COSV61312251; called by muse, mutect2, varscan2
- FAIM2 | c.693C>T p.L231= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV57739565; called by muse, mutect2
- FAR2 | c.1239G>A p.L413= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV51723904, COSV51726080; called by muse, mutect2, varscan2
- FAT2 | c.10344G>A p.L3448= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55820831; called by muse, mutect2, varscan2
- FOXD4 | c.948G>T p.A316= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100070709; called by mutect2, varscan2
- FRZB | c.972C>A p.R324= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54554321; called by muse, mutect2, varscan2
- GMIP | c.552A>G p.K184= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52556755; called by muse, mutect2, varscan2
- GPM6A | c.141T>G p.G47= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV54545123; called by muse, mutect2, varscan2
- GRIA1 | c.1081C>A p.R361= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV53605708; called by muse, mutect2, varscan2
- HDAC9 | c.1542G>T p.A514= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV67765683, COSV67774436; called by muse, mutect2, varscan2
- HEY2 | c.852G>T p.G284= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as COSV64240034; called by muse, mutect2, varscan2
- HTR1F | c.465T>A p.S155= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60389882; called by muse, mutect2, varscan2
- HTR2A | c.1179G>T p.R393= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV101096607; called by muse, mutect2, varscan2
- IGKV1-6 | c.69C>A p.A23= | Silent (SNP) | VAF 67/301 reads (22%) | called by muse, mutect2, varscan2
- KDM4C | c.408A>T p.A136= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV67187242; called by muse, mutect2, varscan2
- KPNB1 | c.1530C>T p.L510= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as rs1192055854, COSV51597367; called by muse, mutect2
- LMF1 | c.855G>T p.R285= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV51897589; called by muse, mutect2, varscan2
- LPCAT1 | c.1017G>T p.R339= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV52038094; called by muse, mutect2, varscan2
- LRP1B | c.4836C>T p.D1612= | Silent (SNP) | VAF 7/129 reads (5%) | catalogued as COSV67227634; called by muse, mutect2
- MAPKAPK5 | c.993G>A p.Q331= | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as rs1415775099, COSV73436091; called by muse, mutect2, varscan2
- MIP | c.336C>A p.V112= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV57511931; called by muse, mutect2, varscan2
- MMP27 | c.1488C>T p.S496= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV52781188; called by muse, mutect2, varscan2
- MPO | c.1005C>T p.S335= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs555802990, COSV56564517; called by muse, mutect2, varscan2
- MUC21 | c.1095C>A p.S365= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV100888842; called by muse, mutect2, varscan2
- MYH14 | c.5397G>A p.K1799= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV51819971; called by muse, mutect2, varscan2
- MYO18B | c.5670G>T p.A1890= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs374392610, COSV59135996; called by muse, mutect2, varscan2
- NATD1 | c.309C>T p.P103= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- NCOA1 | c.1153C>A p.R385= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV56045216, COSV99945740; called by muse, mutect2, varscan2
- NIPAL2 | c.255C>T p.F85= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV57840367; called by muse, mutect2
- NLRP3 | c.987C>T p.L329= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV100276446, COSV60219909; called by muse, mutect2, varscan2
- OR14C36 | c.672C>A p.L224= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV58601495, COSV58602585; called by muse, mutect2, varscan2
- OR2A14 | c.795T>C p.H265= | Silent (SNP) | VAF 124/266 reads (47%) | catalogued as rs1461884365, COSV68718226; called by muse, varscan2
- OR2T3 | c.90C>A p.A30= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100613138; called by muse, mutect2, varscan2
- OR52E2 | c.858A>T p.P286= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100384689; called by muse, mutect2, varscan2
- OR7D4 | c.597G>A p.L199= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs377419980, COSV58072318; called by muse, mutect2, varscan2
- OTOL1 | c.1074C>T p.I358= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100019802; called by muse, mutect2, varscan2
- PAPPA2 | c.249C>A p.P83= | Silent (SNP) | VAF 86/256 reads (34%) | catalogued as rs1419744359, COSV62776409, COSV62779286; called by muse, mutect2, varscan2
- PCDHB2 | c.1623G>A p.P541= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs782450726, COSV99164373; called by muse, mutect2, varscan2
- PCLO | c.7905A>G p.S2635= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs755712630, COSV61626077, COSV61639040; called by muse, mutect2, varscan2
- PCSK1 | c.852C>A p.A284= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV60735661; called by muse, mutect2, varscan2
- PDZD2 | c.1512C>G p.R504= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV56859909, COSV99225575; called by muse, mutect2, varscan2
- PIWIL2 | c.2544G>T p.V848= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as COSV63251855; called by muse, mutect2, varscan2
- POM121L12 | c.162C>A p.P54= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV101374881, COSV68692443; called by muse, mutect2
- PRSS55 | c.330A>G p.L110= | Silent (SNP) | VAF 74/258 reads (29%) | catalogued as COSV60808442; called by muse, mutect2, varscan2
- RARB | c.669C>G p.G223= (on ENST00000383772 / NM_001290216.2; = p.G216= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV58067851; called by muse, mutect2, varscan2
- RASA3 | c.1695G>T p.G565= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV61868053; called by muse, mutect2, varscan2
- REV1 | c.1698T>C p.A566= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV51485924; called by muse, mutect2
- RIMS2 | c.4380C>G p.A1460= (on ENST00000666250 / NM_001348490.2; = p.A1031= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV51686846, COSV99169232; called by muse, mutect2
- ROBO3 | c.1242G>T p.V414= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV101184954; called by muse, mutect2
- RYR2 | c.2949G>A p.L983= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs926827556, COSV100772107, COSV63688668; called by muse, mutect2, varscan2
- SH2D7 | c.399C>A p.P133= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100174605; called by muse, mutect2
- SLC18A1 | c.1498C>A p.R500= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV52348541; called by muse, mutect2, varscan2
- SLC5A7 | c.1134T>A p.V378= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV50892522; called by muse, mutect2, varscan2
- SNX7 | c.483A>G p.P161= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2
- SOX7 | c.246G>A p.S82= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs769113063, COSV58730973; called by muse, mutect2, varscan2
- SYVN1 | c.465C>T p.F155= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs1480119637, COSV53695522; called by muse, mutect2, varscan2
- THSD7A | c.4407T>C p.C1469= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV70265645; called by muse, mutect2
- THSD7B | c.1281G>A p.T427= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs563732139, COSV55693111, COSV99760095; called by muse, mutect2, varscan2
- TMEFF1 | c.300A>G p.Q100= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs150250818; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4599C>T p.S1533= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs138321958; called by muse, mutect2, varscan2
- TNR | c.786G>A p.R262= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV54888579; called by muse, mutect2, varscan2
- TTLL7 | c.60A>T p.T20= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs773279260, COSV53084947; called by muse, mutect2, varscan2
- TTN | c.71637A>T p.I23879= (on ENST00000591111; = p.I16455= on NM_003319.4) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100600109; called by muse, mutect2, varscan2
- TTPA | c.636A>G p.P212= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99478432; called by mutect2, varscan2
- ZBTB39 | c.1788G>A p.L596= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100267940; called by muse, mutect2, varscan2
- ZFYVE1 | c.2052C>T p.A684= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs780060169, COSV59611370; called by muse, mutect2, varscan2
- ZMAT1 | c.1272A>C p.T424= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV100858715; called by muse, mutect2, varscan2
- ZNF33A | c.51G>T p.V17= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV56725343; called by muse, mutect2, varscan2
- ZNF804B | c.3909C>A p.A1303= | Silent (SNP) | VAF 49/216 reads (23%) | catalogued as COSV60830430; called by muse, mutect2, varscan2
- AKR1D1 | c.690-104G>C | Intron (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99652881; called by muse, mutect2
- ANKRD33 | c.-224C>A | 5'UTR (SNP) | VAF 6/84 reads (7%) | catalogued as COSV56606540; called by muse, mutect2
- C1orf122 | c.*92C>T | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs1291969496, COSV65990372; called by muse, mutect2, varscan2
- DCHS2 | n.440G>T | RNA (SNP) | VAF 10/47 reads (21%) | catalogued as COSV59727981; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446623 C>A | 3'Flank (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- GPM6B | c.61+9149C>T | Intron (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100366080; called by muse, mutect2, varscan2
- KRTAP19-8 | c.-1C>T | 5'UTR (SNP) | VAF 7/133 reads (5%) | catalogued as COSV101239173; called by muse, mutect2
- MGAM | c.4618+1948C>T | Intron (SNP) | VAF 17/76 reads (22%) | catalogued as COSV72073654; called by muse, mutect2, varscan2
- NR1I2 | c.-23+456G>T | Intron (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100561419; called by muse, varscan2
- OR2U1P | n.374G>C | RNA (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- RRM2 | n.433G>C | RNA (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- SENP1 | c.221-239G>T | Intron (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99136823; called by muse, mutect2
- SLC39A4 | c.193-80C>T | Intron (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99433092; called by muse, mutect2, varscan2
- SSPOP | n.2770G>T | RNA (SNP) | VAF 12/124 reads (10%) | catalogued as COSV50487739; called by muse, mutect2
- SSPOP | n.6584G>T | RNA (SNP) | VAF 17/78 reads (22%) | catalogued as COSV50487742; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100453 G>T | 3'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
